Somatic mutation profile of tumor specimen 0DKDDB from CCDI case PBBXYA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 6.5 years (2,370 days).
Specimen 0DKDDB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bc8ef487-e200-4eb2-bcff-9668824e583d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKDBW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dbfffe22-b9d6-49a0-a0b5-1d88cb0537a0

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Intron 2, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKZF1 | c.1724C>T p.A575V | Missense Mutation (SNP) | VAF 212/716 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs545546589, COSV55478697; called by muse, varscan2
- ANO2 | c.531C>A p.S177R (on ENST00000356134 / NM_001278597.3; = p.S181R on NM_001278596.3) | Missense Mutation (SNP) | VAF 116/291 reads (40%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.491); catalogued as COSV100502032; called by muse, varscan2
- BCL9L | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 129/988 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as rs1224723516; called by muse, varscan2
- DNAH9 | c.11359G>A p.A3787T | Missense Mutation (SNP) | VAF 240/805 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374061400; called by muse, varscan2
- DOHH | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1183468032, COSV51745363; called by muse, varscan2
- FRG2 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 267/2052 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV66460548; called by muse, varscan2
- GPR160 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 106/960 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs766892041; called by muse, varscan2
- NCOA4 | c.404C>T p.S135L | Missense Mutation (SNP) | VAF 188/656 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as rs199757949; called by muse, varscan2
- RIPOR3 | c.52G>A p.V18I | Missense Mutation (SNP) | VAF 262/991 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs1364965218; called by muse, varscan2
- RPH3A | c.1207G>C p.D403H (on ENST00000389385 / NM_001143854.2; = p.D399H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 222/726 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs202194176; called by muse, varscan2
- TAAR6 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 324/1118 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs866820133, COSV51584773; called by muse, varscan2
- TBRG4 | c.1865G>C p.R622P | Missense Mutation (SNP) | VAF 118/678 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.854); catalogued as COSV51832961; called by muse, varscan2
- THBS3 | c.1882G>A p.D628N | Missense Mutation (SNP) | VAF 150/436 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs779094112; called by muse, varscan2
- CADM2 | c.509A>C p.K170T (on ENST00000407528 / NM_001167674.2; = p.K172T on NM_153184.4) | Missense Mutation (SNP) | VAF 228/725 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.067); called by muse, varscan2
- CFAP65 | c.467G>T p.W156L (on ENST00000341552 / NM_194302.4; = p.W91L on NM_152389.4) | Missense Mutation (SNP) | VAF 194/922 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COPB1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 121/1042 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- COQ8B | c.151G>T p.G51W | Missense Mutation (SNP) | VAF 200/692 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.571); called by muse, varscan2
- ECHDC2 | c.680_697del p.L227_L232del (on ENST00000371522 / NM_001198961.2; = p.L196_L201del on NM_018281.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 96/540 reads (18%) | called by pindel, varscan2
- ELL2 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 175/507 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.399); called by muse, varscan2
- ESPN | c.1732G>A p.G578R | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.187); called by muse, varscan2
- GPBP1 | c.1289dup p.N430Kfs*11 | Frame Shift Ins (INS) | VAF 206/842 reads (24%) | called by pindel, varscan2
- MTMR7 | c.866-1G>A p.X289_splice | Splice Site (SNP) | VAF 310/2380 reads (13%) | called by muse, varscan2
- OR5L2 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 219/1933 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- PERP | c.550G>T p.A184S | Missense Mutation (SNP) | VAF 232/766 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, varscan2
- PRUNE2 | c.1388T>A p.L463H | Missense Mutation (SNP) | VAF 202/640 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, varscan2
- SYNE2 | c.19907G>C p.R6636P | Missense Mutation (SNP) | VAF 228/918 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); called by muse, varscan2
- CROT | c.1053A>G p.G351= | Silent (SNP) | VAF 242/1011 reads (24%) | called by muse, varscan2
- DOT1L | c.2205G>A p.T735= | Silent (SNP) | VAF 77/414 reads (19%) | catalogued as rs374885552; called by muse, varscan2
- LMAN1L | c.75G>A p.T25= | Silent (SNP) | VAF 142/571 reads (25%) | catalogued as rs770469327, COSV100547572, COSV100547717; called by muse, varscan2
- MYH6 | c.3154C>A p.R1052= | Silent (SNP) | VAF 322/1334 reads (24%) | catalogued as COSV62449874; called by muse, varscan2
- OTUD7A | c.2073C>T p.A691= (on ENST00000307050 / NM_001382637.1; = p.A684= on NM_130901.3) | Silent (SNP) | VAF 104/563 reads (18%) | catalogued as rs1296014060; called by muse, varscan2
- ITGB4 | c.2783-44T>C | Intron (SNP) | VAF 234/596 reads (39%) | called by muse, varscan2
- PGA3 | c.56+19G>T | Intron (SNP) | VAF 104/844 reads (12%) | called by muse, varscan2
